TARGET case TARGET-30-PANGXK — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9da8ea16-845b-5cce-bf31-ec0a82ebc871

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C47.3; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of thorax; Classification of tumor: primary; Age at diagnosis: 3.5 years (1,266 days); Year of diagnosis: 2004; Days to last follow up: 3,792 days (10.4 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Necrosis percent: 5; Percent tumor nuclei: 95.
   Treatment given: Protocol identifier: ALTE03N1.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL02P1.

Follow-up (2 entries)
- Days to follow up: 1,855 days (5.1 years); Days to first event: 1,855 days (5.1 years); First event: Event.
- Days to follow up: 3,792 days (10.4 years); Year of follow up: 2015.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PANGXK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PANGXK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 3792
- Protocol: ANBL02P1, ANBL00B1, ALTE03N1
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- MKI: Low
- Diagnostic Category: Ganglioneuroblastoma, nodular
- ICDO Description: Peripheral nerves and Autonomic nervous system of thorax Peripheral nerves and Autonomic nervous system of (see list under C47): . Axilla . Chest . chest wall . thoracic wall . infraclavicular region . scapular region Intercostal nerve
- Percent Necrosis: 5
- Percent Tumor v/s Stroma: 95/5
